Somatic mutation profile of tumor specimen MMRF_2737_1_BM_CD138pos (aliquot MMRF_2737_1_BM_CD138pos_T1_KHS5U_L14886) from MMRF case MMRF_2737, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2737_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61ac10b4-1fb2-425c-96f2-cc284199dcd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2737_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2737_1_PB_WBC_C3_KHS5U_L14887; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6967b96-fde0-4464-af8b-5bcc9fec989f

The open-access MAF lists 78 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 22, Silent 12, Intron 6, 3'Flank 4, RNA 4, Nonsense Mutation 2, 5'Flank 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 63/136 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL7A | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1020885531, COSV99946744; called by muse, mutect2, varscan2
- CALCOCO1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1030520322, COSV100017258; called by muse, mutect2, varscan2
- FTMT | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 279/426 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as rs753267058, COSV100360363; called by muse, mutect2, varscan2
- GNGT1 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); catalogued as COSV99949884; called by muse, mutect2, varscan2
- IGHV2-70 | c.219T>G p.D73E | Missense Mutation (SNP) | VAF 80/83 reads (96%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs181059057; called by muse, varscan2
- IGHV2-70 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs549341348; called by muse, varscan2
- IGHV3-23 | c.18C>G p.S6R | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as rs375458710; called by muse, mutect2, varscan2
- IGLL5 | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs1452780748; called by muse, varscan2
- OR10H3 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59945122; called by muse, mutect2, varscan2
- PPP2R3A | c.3014G>A p.C1005Y | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs762577242, COSV53863173; called by muse, mutect2, varscan2
- ZIM2 | c.792A>C p.K264N | Missense Mutation (SNP) | VAF 122/183 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99690423; called by muse, mutect2, varscan2
- CLHC1 | c.628T>G p.L210V | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DBNL | c.845G>A p.R282K (on ENST00000448521 / NM_001014436.3; = p.R283K on NM_014063.7) | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EVC2 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2, varscan2
- FIP1L1 | c.806C>G p.P269R | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- H2BC4 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- IGSF1 | c.1856C>G p.T619S | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ILVBL | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MAGED1 | c.1735G>T p.E579* | Nonsense Mutation (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- PAGE5 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 113/310 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PFAS | c.2900G>T p.R967L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- RFPL3 | c.100_101del p.F34Pfs*108 (on ENST00000249007 / NM_001098535.1; = p.F5Pfs*108 on NM_006604.2) | Frame Shift Del (DEL) | VAF 38/364 reads (10%) | called by mutect2, varscan2
- RNF145 | c.1267C>G p.Q423E (on ENST00000424310 / NM_001199383.2; = p.Q451E on NM_144726.2) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- THOC5 | c.1709A>C p.N570T | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TSPYL4 | c.1162G>C p.G388R | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TXNRD3 | c.543A>C p.K181N | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.166); called by muse, mutect2
- UNC13B | c.1244G>C p.S415T | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANO10 | c.207A>G p.L69= | Silent (SNP) | VAF 41/278 reads (15%) | called by muse, mutect2, varscan2
- CXorf21 | c.618T>G p.S206= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as COSV100973358; called by muse, mutect2, varscan2
- EEF1A2 | c.345C>A p.I115= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs138846735; called by muse, mutect2, varscan2
- ELFN2 | c.1383G>A p.E461= | Silent (SNP) | VAF 136/308 reads (44%) | catalogued as rs760924048; called by muse, mutect2, varscan2
- HSD3B7 | c.1026C>T p.F342= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs532045637, COSV99287895; called by muse, mutect2, varscan2
- KIRREL3 | c.1296C>T p.H432= | Silent (SNP) | VAF 163/440 reads (37%) | catalogued as rs1246949200, COSV69383612; called by muse, mutect2, varscan2
- KPNA7 | c.630C>G p.T210= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs1370513144; called by muse, mutect2
- MAML3 | c.1497G>A p.Q499= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs574825040, COSV59075209; called by muse, varscan2
- OR10A3 | c.861G>A p.P287= | Silent (SNP) | VAF 129/506 reads (25%) | catalogued as rs200152269; called by muse, mutect2, varscan2
- PNLIPRP3 | c.624C>T p.P208= | Silent (SNP) | VAF 83/174 reads (48%) | catalogued as rs768519982; called by muse, mutect2, varscan2
- TENM3 | c.3273G>C p.L1091= | Silent (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- TTLL9 | c.273C>T p.Y91= | Silent (SNP) | VAF 68/135 reads (50%) | called by muse, mutect2, varscan2
- AC018563.1 | n.619G>T | RNA (SNP) | VAF 128/254 reads (50%) | called by muse, mutect2, varscan2
- ARMCX3 | c.*1033T>G | 3'UTR (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- ATRX | c.*2937T>G | 3'UTR (SNP) | VAF 36/65 reads (55%) | called by muse, mutect2, varscan2
- BHLHE40-AS1 | n.966-207A>T | Intron (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- BMPR1B | chr4:95155693 C>A | 3'Flank (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- C14orf132 | c.*6760T>C | 3'UTR (SNP) | VAF 42/70 reads (60%) | called by muse, mutect2
- C14orf132 | c.*6761T>A | 3'UTR (SNP) | VAF 43/71 reads (61%) | called by muse, mutect2
- C1orf21 | c.*5627C>G | 3'UTR (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- CHIC1 | c.*1779T>C | 3'UTR (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- CHL1 | chr3:407302 C>A | 3'Flank (SNP) | VAF 80/125 reads (64%) | called by muse, mutect2, varscan2
- CHODL | c.-28C>G | 5'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- CLN8 | c.*983A>T | 3'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs1327198736; called by muse, varscan2
- CPNE6 | c.777+47G>A | Intron (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- CRAMP1 | c.*2188C>T | 3'UTR (SNP) | VAF 59/131 reads (45%) | catalogued as rs539202297; called by muse, mutect2, varscan2
- CYP2A7P1 | n.580del | RNA (DEL) | VAF 56/203 reads (28%) | called by mutect2, pindel, varscan2
- DCHS2 | n.6052A>T | RNA (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- DGKG | c.*546G>A | 3'UTR (SNP) | VAF 36/138 reads (26%) | catalogued as rs1370049686; called by muse, mutect2, varscan2
- FRMD3 | c.596+3601G>A | Intron (SNP) | VAF 17/399 reads (4%) | called by muse, mutect2
- G6PD | chrX:154531956 G>A | 3'Flank (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899528 A>T | 3'Flank (SNP) | VAF 75/145 reads (52%) | called by muse, mutect2, varscan2
- ITGA2 | c.*46G>T | 3'UTR (SNP) | VAF 85/355 reads (24%) | called by muse, mutect2, varscan2
- NBN | c.*2062T>C | 3'UTR (SNP) | VAF 67/68 reads (99%) | called by muse, mutect2, varscan2
- NDUFB8 | chr10:100529971 C>T | 5'Flank (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- NRXN1 | c.*794G>T | 3'UTR (SNP) | VAF 34/118 reads (29%) | catalogued as rs201449684; called by muse, mutect2, varscan2
- PARP4P2 | n.760C>G | RNA (SNP) | VAF 70/73 reads (96%) | called by muse, mutect2, varscan2
- PITPNC1 | c.*22G>A | 3'UTR (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- POLR3D | c.*630G>A | 3'UTR (SNP) | VAF 68/130 reads (52%) | called by muse, mutect2, varscan2
- PRDM5 | c.866-1252T>G | Intron (SNP) | VAF 15/30 reads (50%) | called by muse, varscan2
- PTPRE | c.-30-17308G>A | Intron (SNP) | VAF 65/199 reads (33%) | catalogued as rs1242595302; called by muse, mutect2, varscan2
- SCGN | c.*237C>T | 3'UTR (SNP) | VAF 81/172 reads (47%) | called by muse, mutect2, varscan2
- SLC17A5 | c.*490G>C | 3'UTR (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- SLC24A3 | c.*1585C>T | 3'UTR (SNP) | VAF 38/66 reads (58%) | catalogued as rs144954252; called by muse, mutect2, varscan2
- SMG8 | c.1759+84_1759+85insGGT | Intron (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- TM2D2 | c.*94T>G | 3'UTR (SNP) | VAF 35/35 reads (100%) | called by muse, mutect2, varscan2
- TMEM203 | c.*666_*672dup | 3'UTR (INS) | VAF 55/144 reads (38%) | called by mutect2, varscan2
- TMSB15A | c.*15C>A | 3'UTR (SNP) | VAF 88/215 reads (41%) | called by muse, mutect2, varscan2
- UBFD1 | c.*2195T>C | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- UVSSA | c.*1747C>T | 3'UTR (SNP) | VAF 25/83 reads (30%) | catalogued as rs1264067444; called by muse, mutect2, varscan2
